CCDI case PBCPEI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/ffe6ad09-1489-4370-8d40-dce8e00778f4

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.4 years (5,987 days).

Biospecimens (2 samples)
- Sample 0DWVEG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWVFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
